Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A5RJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A5RJ-01A (Primary Tumor).

[page 1 of 6]
Gender

M

Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Final

Results

Source of Specimen

- A. LEFT DISTAL URETER FS-
- B. RIGHT DISTAL URETER FS-
- C. RIGHT COMMON AND EXTERNAL ILIAC LYMPH NODES-
- D. RIGHT OBTURATOR LYMPH NODES-
- E. RIGHT INTERNAL ILIAC LYMPH NODES-
- F. LEFT COMMON AND INTERNAL LYMPH NODES-
- G. LEFT OBTURATOR LYMPH NODES-
- H. BLADDER, PROSTATE GLAND, SEMINAL VESICLES AND VASA DEFERENTIA-

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER FS-
URETER, NEGATIVE FOR TUMOR.
- B. RIGHT DISTAL URETER FS-
URETER, NEGATIVE FOR TUMOR.
- C. RIGHT COMMON AND EXTERNAL ILIAC LYMPH NODES-
FOUR LYMPH NODES, NEGATIVE FOR TUMOR.
- D. RIGHT OBTURATOR LYMPH NODES-
SIX LYMPH NODES, NEGATIVE FOR TUMOR.
- E. RIGHT INTERNAL ILIAC LYMPH NODES-
FATTY TISSUE, NEGATIVE FOR TUMOR.
- F. LEFT COMMON AND INTERNAL LYMPH NODES-
FATTY TISSUE, NEGATIVE FOR TUMOR.
- G. LEFT OBTURATOR LYMPH NODES-
TWO LYMPH NODES, NEGATIVE FOR TUMOR.
- H. BLADDER, PROSTATE GLAND, SEMINAL VESICLES AND VASA DEFERENTIA-
HIGH GRADE PAPILLARY UROTHELIAL CARCINOMA.

ICD-0-3

Carcinoma, papillary urothelial
8130/3

Final

Site: bladder wall, posterior c67.4

fw

2/17/13

[page 2 of 6]
DEPTH OF INVASION: OUTER ONE-THIRD OF MUSCULARIS PROPRIA.

TUMOR SITE: POSTERIOR WALL, URINARY BLADDER.

SQUAMOUS DIFFERENTIATION: PRESENT.

GLANDULAR DIFFERENTIATION: ABSENT.

TUMOR SIZE: 3.5 CM.

HISTOLOGIC GRADE: 3/3.

SPECIMEN TYPE: RADICAL CYSTECTOMY AND PROSTATECTOMY.

TNM STAGE: pT2b, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 12

LYMPHATIC (SMALL VESSEL) INVASION: PROBABLY PRESENT.

ASSOCIATED UROTHELIAL DYSPLASIA: PRESENT.

BENIGN PROSTATIC HYPERPLASIA AND HIGH GRADE PROSTATIC
INTRAEPITHELIAL NEOPLASIA, NEGATIVE FOR INVASIVE TUMOR IN
PROSTATE.

SEMINAL VESICLES, NEGATIVE FOR TUMOR.

NO TUMOR SEEN AT RESECTIONS MARGINS OF PROSTATE, URETHRA,
URETERS AND SOFT TISSUE.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT DISTAL URETER, FS: NO TUMOR SEEN.

RIGHT DISTAL URETER, FS: NO TUMOR SEEN.

FS performed by Dr.

(Frozen Section Signed

[page 3 of 6]
Case Clinical Information
BLADDER CANCER AND UMBILICAL HERNIA REPAIR

Gross Description

- A. Received in formalin labeled with the patient's name and "left distal ureter-FS" is a yellow/tan fibroadipose tissue measuring 5 x 3 x 1 mm thick. Entirely submitted in A1.
- B. Received in formalin labeled with the patient's name and "right distal ureter-FS" is a yellow/tan soft tissue measuring 5 x 2 x 1 mm. Entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "right common and external iliac lymph nodes" is an aggregate of fibroadipose tissue measuring 3 x 3 x 3 cm in compact aggregate. There is a rather subtle induration. Entirely submitted in C1-C3.
- D. Received in formalin labeled with the patient's name and "right obturator lymph nodes" is an aggregate of five fibroadipose tissue fragments measuring 3 x 3 x 3 cm in compact aggregate. One dominant area of induration is bisected in D1. The remainder of the tissue shows more subtle induration. Entirely submitted in D2, D3.
- E. Received in formalin labeled with the patient's name and "right internal iliac lymph nodes" is fibroadipose tissue measuring 2.5 x 2.5 x 2.5 cm in compact aggregate. Minimal induration is encountered. Entirely submitted in E1-E3.
- F. Received in formalin labeled with the patient's name and "left common and internal lymph nodes" is an aggregate of finely divided fat measuring 2.5 x 2.5 x 2.5 cm in compact aggregate. No definite gross lymph node. Entirely submitted in F1-F3.
- G. Received in formalin labeled with the patient's name and "left obturator lymph nodes" is an aggregate of finely divided fat measuring 3.5 x 3.5 x 3 cm in compact aggregate. Dominant induration. Bisected, wrapped and entirely submitted in G1, G2. Additional areas of more subtle induration are submitted in G3.
- H. Received in formalin labeled with the patient's name and "bladder, prostate and seminal vesicles and vas deferentia" is a specimen so designated to include substantial perivesical fat measuring overall 17 cm superior to inferior, 18 cm right to left and 7 cm anterior to posterior. The specimen has been inked blue on the right; black, left. The included prostate measures 5 cm right to left, 3 cm anterior to posterior and 4 cm superior to inferior. The bladder cavity measures 3.5 cm superior to inferior, 3 cm right to left and 2.5 cm anterior to posterior. The posterior midline bladder cavity reveals a bulging, friable, brown/tan and polypoid tumor measuring 3.5 x 3 cm in greater dimensions. The right and left seminal vesicles

[page 4 of 6]
are palpated posteriorly at 2.5 x 1.3 x 1 cm and 2.2 x 1.5 x 1 cm. The right and left vas deferentia track along the posterior bladder wall at 7 cm on the right and 4 cm on the left. Both the right and left ureter stubs are engaged in plastic clips. The left is deeply retracted. The right is flush with the bladder surface. The posterior aspect of the bladder also reveals staple lines. The section code is as follows: H1=left vas and ureter margins; H2=right vas and ureter margins; H3=additional left vas and left seminal vesicle; H4, H5=additional right vas and right seminal vesicle at junction with prostate; H6=shave of distal prostate margin; H7-H9=posterior mid-prostate; H10-H12=posterior/superior prostate; H13, H14 and H15, H16=full-thickness sagittal plane sections extending from polypoid tumor to posterior prostate resection margin; and H17-H20=additional sections of tumor including relationship to prostate not to include resection margin.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
F. AA ROUTINE H&E X1 BLOCK.3

Prepar

[page 5 of 6]
H&E X1
G. AA ROUTINE H&E X1 BLOCK.1
H&E X1
G. AA ROUTINE H&E X1 BLOCK.2
H&E X1
G. AA ROUTINE H&E X1 BLOCK.3
H&E X1
H. AA ROUTINE H&E X1 BLOCK.1
H&E X1
H. AA ROUTINE H&E X1 BLOCK.2
H&E X1
H. AA ROUTINE H&E X1 BLOCK.3
H&E X1
H. AA ROUTINE H&E X1 BLOCK.4
H&E X1
H. AA ROUTINE H&E X1 BLOCK.5
H&E X1
H. AA ROUTINE H&E X1 BLOCK.6
H&E X1
H. AA ROUTINE H&E X1 BLOCK.7
H&E X1
H. AA ROUTINE H&E X1 BLOCK.8
H&E X1
H. AA ROUTINE H&E X1 BLOCK.9
H&E X1
H. AA ROUTINE H&E X1 BLOCK.10
H&E X1
H. AA ROUTINE H&E X1 BLOCK.11
H&E X1
H. AA ROUTINE H&E X1 BLOCK.12
H&E X1
H. AA ROUTINE H&E X1 BLOCK.13
H&E X1
H. AA ROUTINE H&E X1 BLOCK.14
H&E X1
H. AA ROUTINE H&E X1 BLOCK.15
H&E X1
H. AA ROUTINE H&E X1 BLOCK.16
H&E X1
H. AA ROUTINE H&E X1 BLOCK.17
H&E X1
H. AA ROUTINE H&E X1 BLOCK.18
H&E X1
H. AA ROUTINE H&E X1 BLOCK.19
H&E X1
H. AA ROUTINE H&E X1 BLOCK.20
H&E X1

Prepared

[page 6 of 6]
Prepared f.

Source: NCI Genomic Data Commons file dd9c5087-408c-421a-921c-c33534520f2d (TCGA-K4-A5RJ.19AA5671-7AE1-49F3-8CF0-03D2871AFCCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).